Surgical pathology report (de-identified scan), TCGA case TCGA-56-8624, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8624-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

COPY TO:

IO Consultation

Frozen Section Diagnosis: "Large cell carcinoma consistent with squamous cell carcinoma,

reported to Dr. [REDACTED], positive patient ID"

Performed by Dr. [REDACTED] Campus

Pre-Op Diagnosis

Right lung cancer

Post-Op Diagnosis

Same

Clinical History

Nothing indicated on requisition

Gross Description:

Three parts

Container labeled "[REDACTED] - level 9 lymph node" is a 0.3 x 0.2 x 0.1 cm irregular fragment of soft gray black tissue entirely submitted in a single cassette.

Container labeled "[REDACTED] - level 4 lymph node right lung" is a 0.7 x 0.5 x 0.3 cm of gray pink irregular tissue fragments which are entirely submitted in a single cassette.

Container labeled "[REDACTED] - right lower lobe right lung" is a 199 gram previously partially sectioned portion of recognizable pulmonary parenchyma grossly consistent with right lower lobe of lung. This measures as received 15.5 x 10.5 x 5.6 cm and has as its margin of resection stapled bifurcated tertiary bronchi. The pleural is wrinkled pink red and moderately anthracotic streaked. Noted on the lateral aspect at a point 6 cm from the apex there is a 1.1 x 1.0 cm umbilicated indurated gray tan plaque. Noted on the anterior aspect at the base is a 3.0 x 3.0 x 3.0 cm area of indurated umbilication. Both of these areas are previously sectioned. The smaller portion has a 1.5 x 1.5 x 1.1 cm

[page 2 of 3]
lobulated plaque-like lesion with gray tan fibrotic cut surface and slight lobulation. The larger portion has a similar cut surface. Both of these extend to but not through the pleura grossly. The smaller portion is noted 2.0 cm from the nearest bronchial margin while the larger portion is 3.9 cm from the bronchial margin. A discrete recognizable bronchial connection is not present on either portion. The specimen is received after tissue harvest for genomic study. Within the specimen container are two tissue cassettes labeled [REDACTED]. In addition a portion of the smaller lateral lesion submitted for FS is reported as "large cell carcinoma consistent with squamous cell carcinoma, reported to Dr. [REDACTED] positive patient ID" by Dr. [REDACTED]. On further sectioning both portions reveal a connection to a small bronchus on each lesion. The remaining parenchyma is spongy and pink red with areas of anthracotic streaking. No additional gross lesions are identified. Representative sections are submitted labeled as follows: A - frozen section residue, B - bronchial margin, C through E - remaining smaller lateral lesion, F through H - larger basal lesion to medial pleura, I and J - larger basal lesion to basal pleura, K - random uninvolved parenchyma.

[REDACTED]

Microscopic Description:

Slides reviewed. The frozen section diagnosis is confirmed.

Final Diagnosis

Level 9 lymph node:

Benign, no pathological diagnosis (0/1).

Level 4 lymph node right lung:

Benign, hyperplasia (0/1).

Right lower lobe of lung lobectomy:

Carcinoma.

Tumor characteristics:

Histologic type: Squamous cell carcinoma.

Histologic grade: Moderately differentiated (G2).

Tumor site: Right lower lobe extending to peripheral aspect.

Tumor focality: Multifocal.

Tumor size (of largest mass): 3.0 x 3.0 x 3.0 cm.

Visceral pleural invasion: Not identified.

Lymphovascular space invasion: Findings suspicious for lymphovascular invasion.

Tumor extension: Not identified, appears confined to lung.

Treatment effect: Not identified.

Tumor distance from bronchial margin: 2.0 cm.

Tumor distance from pleural surface: Less than 0.1 cm.

Lymph node status: (utilizing all specimens):

Total number of lymph nodes received: 2

Total number of lymph nodes containing metastatic carcinoma: None (0/2).

Other significant findings:

Patchy fibrosis and bronchiectasis.

pTN stage: pT1bN0 [REDACTED]

[REDACTED]

Comments

This report has been finalized at the [REDACTED]

[REDACTED]

[REDACTED]

[page 3 of 3]
REVISION:

Upon re-review of the classification of this tumor, as requested by [REDACTED], it is indeed discovered that under the new classification a satellite tumor immediately classifies the neoplasm as a stage T3. The revised classification of this tumor is therefore pT3N0. The remainder of the report is unchanged.

REVISION DATE: [REDACTED]

<Sign Out Dr. Signature>

Source: NCI Genomic Data Commons file 25302362-9261-407f-af52-05b3be13656e (TCGA-56-8624.0C8899E7-79F4-46B1-9184-259F8315EF52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).